MMRF case MMRF_2079 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7eb4b859-1c00-44a6-b771-c9cbc2cb43c4

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 62.8 years (22,942 days); ISS stage: II; Days to last known disease status: 157 days; Days to last follow up: 157 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 2 days; Days to treatment end: 26 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 65 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -29 (ECOG 0): M Protein 5.33 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 53.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Immunoglobulin G 74.4 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.4 g/L; Beta 2 Microglobulin 3.77 µg/mL; Lactate Dehydrogenase 2.25 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 129 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Albumin 24 g/L; Glucose 3.25 mmol/L.
- Day 65 (ECOG 0): M Protein 3.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 34.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.7 mg/dL; Lactate Dehydrogenase 2.07 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 10.5 ×10⁹/L; Absolute Neutrophil 7.3 ×10⁹/L; Platelets 64 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.23 mmol/L; Albumin 25 g/L; Total Protein 8.9 g/dL; Glucose 7.15 mmol/L.
- Day 157 (ECOG 0): M Protein 3.64 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 40.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.67 mg/dL; Lactate Dehydrogenase 1.68 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.2 mmol/L; Albumin 26 g/L; Total Protein 8.9 g/dL; Glucose 3.96 mmol/L.

Other clinical attributes
- Day -29: Weight: 58 kg; Height: 167 cm.

Biospecimens (2 samples)
- Sample MMRF_2079_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -29 days.
- Sample MMRF_2079_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -29 days.
